Gene-level copy-number profile of tumor specimen ALCH-B4BM-TTP1-A from ALCHEMIST case ALCH-B4BM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,027 days).
Specimen ALCH-B4BM-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9fbbd900-3a4d-4fdf-af75-1fd1a67f16d5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4BM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/ed048c42-47ad-47cd-b075-c31312351308

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 5,002; copy number 2: 48,333; copy number 3: 3,153; copy number 4: 1,768; copy number 5: 57; copy number 6: 6; copy number 7: 37; copy number 10: 4.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:70,103,798–70,104,179, 1 gene: H2AZP2.
- chr11:73,395,559–73,396,436, 1 gene (within-gene range 0–2): AP000763.4.
- chr14:93,067,452–93,072,152, 1 gene (within-gene range 0–1): ITPK1-AS1.
- chr15:25,187,536–25,238,067, 28 genes (within-gene range 0–2): SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37.
- chr16:8,847,650–8,870,032, 5 genes (within-gene range 0–2): AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4.
- chr17:795,306–795,794, 1 gene: AC087392.5.
- chr17:2,720,801–2,723,947, 1 gene: AC005696.4.
- chr19:27,757,184–27,760,849, 1 gene (within-gene range 0–2): AC006504.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 104 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–1,747,954, 52 genes, copy number 5: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1.
- chr12:166,856–2,004,535, 39 genes, copy number 6–10 (within-gene range 3–10): AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B.
- chr12:16,347,142–16,788,375, 8 genes, copy number 7: MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1.
- chr12:19,724,435–20,136,163, 5 genes, copy number 5: RNU1-146P, AC024901.1, TCP1P3, LINC02398, LINC02468.

Autosomal genes at a single copy (total copy number 1): 5,002. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
